HCMI case HCM-CSHL-0639-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/4a10c499-7f11-49dc-b865-b6cbaf5b1df7

Demographics
Sex at birth: female; Days to birth: -27,740 days (75.9 years before the index date); Year of birth: 1943; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenoma, borderline malignancy: ICD-O-3 morphology code: 8442/1; ICD-10 code: C56.1; Tissue or organ of origin: Ovary; Site of resection or biopsy: Uterine adnexa; Classification of tumor: primary; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: Yes; Peritoneal fluid cytological status: Malignant; Sites of involvement: Lung, NOS / Adnexa.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Acetylcysteine + Carboplatin + Paclitaxel; Treatment intent type: Neoadjuvant; Days to treatment start: -107 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, for residual disease; neoadjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 0 days.
- Days to follow up: 81 days; Disease response: Stable Disease; Progression or recurrence: No.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 78 kg; Height: 176 cm; BMI: 25.2.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0639-C56-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0639-C56-11A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0639-C56-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0639-C56-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
